Somatic mutation profile of tumor specimen TCGA-H7-8501-01A (aliquot TCGA-H7-8501-01A-11D-2394-08) from TCGA case TCGA-H7-8501, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cheek mucosa; AJCC pathologic stage: Stage IVA; Tumor grade: GX; Age at diagnosis: 54.2 years (19,808 days).
Specimen TCGA-H7-8501-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2a1f02ae-a082-407d-8afe-f4ecf57a165f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-H7-8501-10A (Blood Derived Normal), aliquot TCGA-H7-8501-10A-01D-2394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e62dba2c-cbf9-4300-8ce9-4d5092e2e163

The open-access MAF lists 160 somatic variants for this specimen: 121 protein-altering or splice-affecting, 36 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 106, Silent 36, Nonsense Mutation 11, Intron 3, Splice Site 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 9/22 reads (41%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, mutect2, varscan2
- HRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 46/90 reads (51%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.383); catalogued as rs104894229, CM053283, CM061797, COSV54236795, COSV54236828, COSV54237299; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.488A>G p.Y163C | Missense Mutation (SNP) | VAF 14/67 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148924904, CM942135, COSV52663142, COSV52676381; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACOT11 | c.362C>G p.S121C | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100650483; called by muse, mutect2, varscan2
- ADNP | c.1651G>C p.D551H | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV100823642; called by muse, mutect2, varscan2
- AFF3 | c.2758G>A p.D920N | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.192); catalogued as rs202104245, COSV57863774; called by muse, mutect2, varscan2
- AKAP6 | c.4283C>T p.S1428L | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs537245618, COSV99798410; called by muse, mutect2, varscan2
- ALG11 | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as rs1431111423, COSV101584244; called by muse, mutect2, varscan2
- ARFGAP3 | c.858G>A p.M286I | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV99605110; called by muse, mutect2, varscan2
- ARHGAP36 | c.1353C>G p.I451M | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99357263; called by muse, mutect2, varscan2
- ATXN2L | c.1144C>T p.R382C | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs776614927, COSV57366960; called by muse, mutect2, varscan2
- BAK1 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.255); catalogued as COSV100645820; called by muse, mutect2, varscan2
- BBX | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100361050; called by muse, mutect2, varscan2
- CARF | c.1573G>A p.E525K | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.65); catalogued as rs1211038885, COSV100247502, COSV57547630; called by muse, mutect2, varscan2
- CARMIL2 | c.373G>C p.G125R | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.158); catalogued as COSV100575953; called by muse, mutect2, varscan2
- CASP8 | c.436A>G p.M146V (on ENST00000432109 / NM_033355.3; = p.M178V on NM_001228.4) | Missense Mutation (SNP) | VAF 60/140 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99964654; called by muse, mutect2, varscan2
- CDK13 | c.2098C>T p.R700C | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs760367885, COSV51701735, COSV99475101; called by muse, mutect2, varscan2
- CECR2 | c.1393G>A p.E465K (on ENST00000342247 / NM_001290047.2; = p.E282K on NM_001290046.1) | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.363); catalogued as COSV99377038; called by muse, mutect2, varscan2
- CEP85 | c.455C>G p.S152C | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV99431759; called by muse, mutect2, varscan2
- CLCNKA | c.1572C>G p.I524M | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as COSV100509870; called by muse, mutect2, varscan2
- CLMN | c.1256C>T p.S419F | Missense Mutation (SNP) | VAF 24/155 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV100112075; called by muse, mutect2, varscan2
- CNGA2 | c.1240G>C p.D414H | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100323380; called by muse, varscan2
- DCLRE1C | c.500C>T p.T167M (on ENST00000378278 / NM_001350965.2; = p.T52M on NM_022487.4) | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs149556109; called by muse, mutect2, varscan2
- DDX46 | c.68G>C p.R23T | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); catalogued as COSV100844849, COSV62798722; called by muse, mutect2, varscan2
- DNAJB6 | c.514C>A p.L172I | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV100055285; called by muse, mutect2, varscan2
- DSG1 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57138928, COSV99935588; called by muse, mutect2
- EIF3A | c.769C>T p.H257Y | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV100974495, COSV64962965; called by muse, mutect2, varscan2
- EIF5A | c.366G>C p.E122D | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV100222693, COSV100223047; called by muse, varscan2
- ELOVL3 | c.442C>T p.H148Y | Missense Mutation (SNP) | VAF 40/180 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100892732, COSV64174831; called by muse, mutect2, varscan2
- EP400 | c.2078C>T p.S693L | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as rs765755316, COSV100200450; called by muse, mutect2, varscan2
- EPHB1 | c.2462G>A p.G821E | Missense Mutation (SNP) | VAF 53/304 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101212707; called by muse, mutect2, varscan2
- F2 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.101); catalogued as COSV100319340; called by muse, mutect2, varscan2
- FANCI | c.262G>C p.E88Q | Missense Mutation (SNP) | VAF 54/170 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV100167486; called by muse, mutect2, varscan2
- FAT1 | c.10171G>T p.E3391* | Nonsense Mutation (SNP) | VAF 30/57 reads (53%) | catalogued as COSV71673013; called by muse, mutect2, varscan2
- FBXL7 | c.1386G>T p.Q462H | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100309102; called by muse, mutect2, varscan2
- FGD6 | c.3550G>C p.E1184Q | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV100676378; called by muse, mutect2, varscan2
- FIBCD1 | c.1264C>T p.Q422* | Nonsense Mutation (SNP) | VAF 10/128 reads (8%) | catalogued as COSV99446752; called by muse, mutect2
- FXR2 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 47/212 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.667); catalogued as COSV100007079; called by muse, mutect2, varscan2
- GABRD | c.88G>A p.D30N | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as rs74786356, COSV101059508; called by muse, mutect2, varscan2
- GALNT3 | c.1114G>C p.E372Q | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV67061898, COSV67062128; called by muse, mutect2, varscan2
- GDA | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.48); catalogued as COSV99428787; called by muse, mutect2, varscan2
- GNL2 | c.1993G>T p.E665* | Nonsense Mutation (SNP) | VAF 23/104 reads (22%) | catalogued as COSV56171739, COSV99953480; called by muse, mutect2, varscan2
- GRIA1 | c.227C>A p.S76Y | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99598217; called by muse, mutect2, varscan2
- H6PD | c.545C>T p.S182L | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101072418; called by muse, mutect2, varscan2
- HCN3 | c.1195G>A p.E399K | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100712807, COSV61360221; called by muse, varscan2
- HEG1 | c.1468G>A p.D490N | Missense Mutation (SNP) | VAF 48/233 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.109); catalogued as COSV100230094; called by muse, mutect2, varscan2
- HERC2 | c.7121C>T p.P2374L | Missense Mutation (SNP) | VAF 22/196 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs763664122, COSV99871080; called by muse, mutect2, varscan2
- HERC4 | c.2857G>A p.E953K (on ENST00000395198 / NM_022079.3; = p.E945K on NM_015601.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99516612; called by muse, mutect2, varscan2
- HLA-A | c.19C>T p.R7* | Nonsense Mutation (SNP) | VAF 13/95 reads (14%) | catalogued as COSV65136444, COSV65138215; called by muse, varscan2
- HOXB8 | c.563G>A p.R188K | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV53310164, COSV99493878; called by muse, mutect2, varscan2
- HSPA13 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99579892; called by muse, mutect2, varscan2
- ITGA3 | c.2128C>T p.R710W | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV99143270; called by muse, mutect2, varscan2
- ITGA4 | c.1965G>C p.K655N | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.607); catalogued as rs1273378347, COSV101223115; called by muse, mutect2, varscan2
- ITPR3 | c.7465C>G p.L2489V | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100951965; called by muse, mutect2, varscan2
- KANK2 | c.2341G>T p.E781* (on ENST00000586659 / NM_001379562.1; = p.E789* on NM_015493.7 and 7 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 18/112 reads (16%) | catalogued as COSV100763028; called by muse, mutect2, varscan2
- KIT | c.731C>G p.S244* | Nonsense Mutation (SNP) | VAF 25/131 reads (19%) | catalogued as COSV99853332, COSV99855360; called by muse, varscan2
- KMT2D | c.8695G>A p.G2899S | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.79); catalogued as rs587778472, COSV99977695; ClinVar: not provided; called by muse, mutect2
- KRT74 | c.402G>C p.Q134H | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99977397; called by muse, mutect2, varscan2
- KRTAP10-10 | c.58G>A p.V20I | Missense Mutation (SNP) | VAF 36/168 reads (21%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100551939; called by muse, mutect2, varscan2
- LDAH | c.206C>G p.S69C | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.021); catalogued as rs36063668, COSV52973627, COSV99425362; called by muse, mutect2, varscan2
- MAMDC4 | c.874G>A p.A292T | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.59); PolyPhen benign (0.019); catalogued as rs142114032, COSV99915413; called by mutect2, varscan2
- MAP1B | c.1741G>C p.E581Q | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.96); catalogued as COSV99701813; called by muse, mutect2, varscan2
- ME3 | c.154G>T p.D52Y | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.531); catalogued as COSV100660867, COSV62771883; called by muse, mutect2, varscan2
- MET | c.895A>G p.I299V | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.992); catalogued as COSV100577024, COSV100577444; called by muse, mutect2, varscan2
- MGRN1 | c.678+1G>T p.X226_splice | Splice Site (SNP) | VAF 11/45 reads (24%) | catalogued as rs377465020; called by muse, mutect2, varscan2
- MORC2 | c.759G>T p.M253I (on ENST00000397641 / NM_001303256.3; = p.M191I on NM_014941.3) | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV99309481, COSV99310072; called by muse, mutect2, varscan2
- MOV10L1 | c.1255G>A p.G419R | Missense Mutation (SNP) | VAF 29/170 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as rs752711170, COSV53167220, COSV53167920; called by muse, mutect2, varscan2
- MUC4 | c.15316C>T p.R5106W (on ENST00000463781 / NM_018406.7; = p.R870W on NM_004532.6) | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs1338980774, COSV100203573; called by muse, mutect2, varscan2
- MYC | c.437C>T p.S146L (on ENST00000377970; = p.S161L on NM_002467.6) | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV52367052; called by muse, mutect2, varscan2
- NFAT5 | c.3323C>T p.S1108F | Missense Mutation (SNP) | VAF 50/202 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100590454; called by muse, varscan2
- NID1 | c.1948C>T p.R650C | Missense Mutation (SNP) | VAF 46/236 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs562243335, COSV99937015; called by muse, varscan2
- NPY | c.188+1G>A p.X63_splice | Splice Site (SNP) | VAF 7/30 reads (23%) | catalogued as COSV99635664; called by muse, mutect2, varscan2
- NUP88 | c.395T>A p.M132K | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as COSV99851514; called by mutect2, varscan2
- NXN | c.626G>A p.R209Q | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); catalogued as rs1167755610, COSV100402706; called by muse, mutect2, varscan2
- OBSL1 | c.1413C>G p.I471M | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.139); catalogued as rs1294145402, COSV99216233; called by muse, mutect2
- OR8S1 | c.538G>C p.E180Q | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100043458; called by muse, mutect2, varscan2
- PAPSS1 | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs1484984516, COSV99491788; called by muse, mutect2, varscan2
- PCDH15 | c.4131G>T p.L1377F | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100215472; called by muse, mutect2, varscan2
- PCED1A | c.343C>T p.R115C | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62313286; called by muse, mutect2, varscan2
- PDZRN4 | c.2987T>A p.M996K (on ENST00000402685 / NM_001164595.2; = p.M738K on NM_013377.4) | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.406); catalogued as rs771383365, COSV100113645; called by muse, mutect2, varscan2
- PHRF1 | c.2758G>C p.E920Q (on ENST00000264555 / NM_001286581.2; = p.E919Q on NM_020901.4) | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.257); catalogued as COSV99199494; called by muse, mutect2, varscan2
- PIK3CG | c.938C>T p.P313L | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV100782543; called by muse, mutect2, varscan2
- PLG | c.208G>C p.E70Q | Missense Mutation (SNP) | VAF 30/202 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.424); catalogued as COSV99804260; called by muse, mutect2, varscan2
- POM121L12 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs200929126, COSV68692625; called by muse, mutect2, varscan2
- PTK2 | c.2117G>T p.G706V | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.69); catalogued as COSV100569410; called by muse, mutect2, varscan2
- RAD21 | c.826G>C p.D276H | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as COSV99814808; called by muse, mutect2, varscan2
- RIF1 | c.3244A>T p.M1082L | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV99690089; called by muse, mutect2, varscan2
- ROPN1B | c.562G>C p.E188Q | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.969); catalogued as COSV99305472; called by muse, mutect2, varscan2
- SDK1 | c.5360G>A p.G1787E | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs758511200, COSV101268793, COSV67361291; called by muse, mutect2, varscan2
- SHD | c.547C>A p.Q183K | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV101619024; called by muse, mutect2, varscan2
- SLC6A3 | c.1562G>A p.R521Q | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as rs760024050, COSV54363818; called by muse, mutect2, varscan2
- SLC8A3 | c.1306G>C p.E436Q | Missense Mutation (SNP) | VAF 32/182 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV100775899; called by muse, mutect2, varscan2
- SNRNP200 | c.1330G>A p.E444K | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV100107122; called by muse, mutect2, varscan2
- SOWAHB | c.247G>C p.E83Q | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.087); catalogued as COSV100530598; called by muse, mutect2, varscan2
- SPRED2 | c.935G>A p.C312Y | Missense Mutation (SNP) | VAF 32/145 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100710075; called by muse, mutect2, varscan2
- SPRY4 | c.208G>A p.G70R (on ENST00000434127 / NM_001127496.3; = p.G93R on NM_030964.4) | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as rs1379051928, COSV59985420; called by muse, mutect2, varscan2
- STAT1 | c.2241G>A p.M747I | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as COSV100738449; called by muse, mutect2, varscan2
- SURF4 | c.507C>G p.F169L | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV100914301; called by muse, mutect2, varscan2
- SYNJ2 | c.3529G>T p.E1177* | Nonsense Mutation (SNP) | VAF 11/40 reads (28%) | catalogued as COSV100840026; called by muse, mutect2, varscan2
- TDO2 | c.1001G>A p.R334K | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.37); catalogued as COSV101569951; called by muse, mutect2, varscan2
- TDRD10 | c.171C>G p.F57L | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.184); catalogued as COSV100872973, COSV100873088; called by muse, mutect2, varscan2
- TECPR2 | c.2008G>A p.D670N | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as COSV100849823; called by muse, mutect2, varscan2
- TEKT3 | c.844G>A p.G282S | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs544798302, COSV58628553; called by muse, mutect2, varscan2
- TFPI2 | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV99746591; called by muse, mutect2, varscan2
- TIAM1 | c.1918C>T p.L640F | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV99732901; called by muse, mutect2, varscan2
- TMEM168 | c.2040G>A p.W680* | Nonsense Mutation (SNP) | VAF 8/67 reads (12%) | catalogued as COSV100454499; called by muse, mutect2, varscan2
- TMEM242 | c.32C>G p.P11R | Missense Mutation (SNP) | VAF 40/223 reads (18%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); catalogued as rs587747016, COSV100900857; called by muse, mutect2, varscan2
- TP53 | c.166G>T p.E56* | Nonsense Mutation (SNP) | VAF 52/270 reads (19%) | catalogued as COSV52771366, COSV52826932, COSV52883452; called by muse, mutect2, varscan2
- TRRAP | c.3135G>C p.L1045F | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.528); catalogued as COSV100722001; called by muse, mutect2, varscan2
- TTC37 | c.3991C>T p.Q1331* | Nonsense Mutation (SNP) | VAF 17/88 reads (19%) | catalogued as COSV100706376; called by muse, mutect2, varscan2
- USP11 | c.2833G>T p.A945S (on ENST00000218348; = p.A902S on NM_001371072.1) | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV99510689; called by muse, mutect2, varscan2
- VAV3 | c.448G>C p.E150Q | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.776); catalogued as COSV100579151; called by muse, mutect2, varscan2
- VMP1 | c.1102T>C p.F368L | Missense Mutation (SNP) | VAF 50/287 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.211); catalogued as COSV99229959, COSV99230882; called by muse, mutect2, varscan2
- WDR81 | c.3869T>G p.I1290S (on ENST00000409644 / NM_001163809.2; = p.I239S on NM_152348.4) | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0.038); catalogued as COSV100488551; called by muse, mutect2, varscan2
- ZNF236 | c.3782G>A p.R1261H | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99469114; called by muse, mutect2, varscan2
- ZNF257 | c.1632A>T p.K544N | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as COSV101448023; called by muse, mutect2
- ZZEF1 | c.1724G>A p.G575E | Missense Mutation (SNP) | VAF 29/173 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV101067491; called by muse, mutect2, varscan2
- CYP21A2 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.078); called by muse, varscan2
- GDF5 | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.64); PolyPhen benign (0.001); called by muse, mutect2
- SERPINE1 | c.601_604del p.P201Sfs*23 | Frame Shift Del (DEL) | VAF 23/224 reads (10%) | called by mutect2, pindel, varscan2
- SLC12A9 | c.305_316+27del p.X102_splice | Splice Site (DEL) | VAF 7/86 reads (8%) | called by mutect2, pindel
- AKAP17A | c.81C>T p.I27= | Silent (SNP) | VAF 42/210 reads (20%) | catalogued as rs1263763876, COSV58309624; called by muse, varscan2
- APOB | c.2376C>G p.L792= | Silent (SNP) | VAF 20/103 reads (19%) | catalogued as COSV99263648; called by muse, mutect2, varscan2
- BFSP2 | c.423G>A p.E141= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV100183555; called by muse, mutect2, varscan2
- CAMK1G | c.1359C>A p.V453= | Silent (SNP) | VAF 22/102 reads (22%) | catalogued as COSV50526505, COSV99151637; called by muse, varscan2
- CDKN2A | c.237C>T p.T79= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as COSV58686008, COSV58727031; called by muse, mutect2, varscan2
- CNGA2 | c.1176G>A p.V392= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as COSV100323379; called by muse, varscan2
- CPLANE1 | c.7629C>T p.F2543= | Silent (SNP) | VAF 17/91 reads (19%) | catalogued as COSV99949685; called by muse, mutect2, varscan2
- DAAM2 | c.2475C>G p.L825= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as COSV99224642; called by muse, mutect2, varscan2
- DGKH | c.261C>T p.F87= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV99818346; called by muse, mutect2, varscan2
- DHX57 | c.1113C>T p.L371= | Silent (SNP) | VAF 19/83 reads (23%) | catalogued as rs761062892, COSV99769087; called by muse, mutect2, varscan2
- ENPP5 | c.1023C>T p.Y341= | Silent (SNP) | VAF 30/268 reads (11%) | catalogued as rs754523882, COSV100040285; called by muse, mutect2, varscan2
- EXTL1 | c.399C>T p.L133= | Silent (SNP) | VAF 13/81 reads (16%) | catalogued as rs1429361011, COSV65337719; called by muse, mutect2, varscan2
- GREB1 | c.4602G>C p.V1534= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV99302260; called by muse, mutect2, varscan2
- H2BC5 | c.198C>T p.F66= | Silent (SNP) | VAF 38/220 reads (17%) | catalogued as rs769305558, COSV56801251; called by muse, mutect2, varscan2
- HEXA | c.1344G>A p.Q448= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as COSV99173675, COSV99173870; called by muse, mutect2, varscan2
- KANK1 | c.2289G>A p.Q763= | Silent (SNP) | VAF 23/87 reads (26%) | catalogued as COSV100619444, COSV63217384; called by muse, mutect2, varscan2
- MAN2C1 | c.192C>T p.F64= | Silent (SNP) | VAF 3/10 reads (30%) | catalogued as COSV99145225; called by muse, mutect2
- MAP3K12 | c.1533G>A p.T511= | Silent (SNP) | VAF 11/93 reads (12%) | catalogued as rs757861359, COSV57235382, COSV99913056; called by muse, mutect2, varscan2
- MBD5 | c.3990C>G p.V1330= | Silent (SNP) | VAF 5/76 reads (7%) | called by muse, mutect2
- MGARP | c.159C>T p.G53= | Silent (SNP) | VAF 10/87 reads (11%) | catalogued as rs199662606; called by muse, mutect2, varscan2
- MUC16 | c.11307C>T p.I3769= | Silent (SNP) | VAF 32/156 reads (21%) | catalogued as COSV67472428; called by muse, mutect2
- MYH2 | c.5157T>C p.V1719= | Silent (SNP) | VAF 26/110 reads (24%) | catalogued as COSV99819291; called by muse, mutect2, varscan2
- MYH9 | c.138C>G p.L46= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as rs773127242, COSV53396225; called by muse, mutect2, varscan2
- MYH9 | c.30C>G p.L10= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV53386080, COSV99337895; called by muse, mutect2, varscan2
- NGEF | c.936C>T p.S312= | Silent (SNP) | VAF 22/82 reads (27%) | catalogued as rs199543898, COSV99888040; called by muse, mutect2, varscan2
- OR13J1 | c.255C>T p.L85= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as rs759494405, COSV100940751; called by muse, mutect2, varscan2
- PCDH9 | c.1221C>T p.V407= | Silent (SNP) | VAF 19/105 reads (18%) | catalogued as rs1384361215, COSV100118541; called by muse, mutect2, varscan2
- PPP1R14C | c.372G>A p.E124= | Silent (SNP) | VAF 24/108 reads (22%) | catalogued as COSV100744858; called by muse, mutect2, varscan2
- SH3BP4 | c.1422C>G p.V474= | Silent (SNP) | VAF 30/71 reads (42%) | catalogued as COSV100748996; called by muse, mutect2, varscan2
- SIDT1 | c.1569G>A p.R523= | Silent (SNP) | VAF 20/109 reads (18%) | catalogued as COSV99333178; called by muse, mutect2, varscan2
- SWAP70 | c.858C>T p.I286= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV100013540; called by muse, mutect2, varscan2
- TACR2 | c.597C>T p.L199= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV100964811, COSV64822066; called by muse, mutect2
- TMEM74B | c.531C>T p.I177= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as COSV101121958; called by muse, mutect2, varscan2
- TWNK | c.1230G>A p.L410= | Silent (SNP) | VAF 14/79 reads (18%) | catalogued as COSV99271951; called by muse, mutect2, varscan2
- WWC1 | c.1839G>C p.L613= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as COSV54650762, COSV99514263; called by muse, mutect2
- ZNF215 | c.1155G>A p.G385= | Silent (SNP) | VAF 25/85 reads (29%) | catalogued as COSV53492020; called by muse, mutect2, varscan2
- CTSC | c.318+6807C>T | Intron (SNP) | VAF 17/66 reads (26%) | catalogued as COSV99910501; called by muse, mutect2, varscan2
- PAQR6 | c.760+45G>A | Intron (SNP) | VAF 14/49 reads (29%) | catalogued as COSV99430741; called by muse, varscan2
- SND1 | c.1779+6801A>T | Intron (SNP) | VAF 55/262 reads (21%) | catalogued as COSV100689770; called by muse, mutect2, varscan2
